CCDI case PBCNVZ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Spinal cord, cranial nerves, and other parts of central nervous system.
https://portal.gdc.cancer.gov/cases/999bee62-8b88-48e7-866d-076abed73bda

Demographics
Sex at birth: male.

Diagnoses (1)
1. Myxopapillary ependymoma: ICD-O-3 morphology code: 9394/1; Tissue or organ of origin: Spinal cord; Age at diagnosis: 18.7 years (6,818 days).

Biospecimens (3 samples)
- Sample 0DW6B5: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DW6BB: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DW6C8: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
